Gene-level copy-number profile of tumor specimen ALCH-B0B6-TTP1-A from ALCHEMIST case ALCH-B0B6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.9 years (24,425 days).
Specimen ALCH-B0B6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b70491d0-4730-41bb-b2aa-bd034c460b9f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0B6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/49dc7ce8-c117-4da8-9fe6-e19ba574f72b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 116; copy number 1: 7,858; copy number 2: 45,068; copy number 3: 4,982; copy number 4: 327; copy number 6: 17; copy number 7: 8; copy number 9: 3; copy number 10: 1; copy number 11: 1; copy number 13: 2; copy number 16: 1; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 116 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,359,809–91,621,421, 5 genes (within-gene range 0–1): AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,686,102–91,723,605, 2 genes: AC027612.2, NKAIN1P2.
- chr3:109,176,438–109,723,273, 12 genes (within-gene range 0–2): AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15.
- chr3:128,572,000–128,576,086, 1 gene: LINC01565.
- chr3:153,129,074–153,129,640, 1 gene: AC117394.1.
- chr3:181,866,351–181,867,154, 1 gene: AC007547.1.
- chr4:70,815,783–71,022,449, 3 genes (within-gene range 0–2): GRSF1, RNU6-891P, MOB1B.
- chr4:128,069,014–128,069,612, 1 gene (within-gene range 0–2): AC099340.1.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr8:30,249,502–30,250,092, 1 gene: AC090820.1.
- chr8:33,370,824–33,567,128, 9 genes: FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122.
- chr9:6,532,467–6,727,438, 11 genes (within-gene range 0–2): GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,748,981, 2 genes (within-gene range 0–2): PRELID3BP11, SNRPEP2.
- chr9:125,234,853–125,257,071, 2 genes: HSPA5, AL354710.2.
- chr9:125,372,325–125,417,586, 2 genes: AL627223.1, Metazoa_SRP.
- chr10:13,308,145–13,348,298, 2 genes: RBISP1, SEPHS1.
- chr10:21,321,961–21,497,260, 8 genes: RNU6-15P, LINC02643, RNMTL1P1, AL158209.1, Metazoa_SRP, Y_RNA, MIR1915HG, MIR1915.
- chr10:92,204,229–92,420,875, 6 genes (within-gene range 0–1): AL158040.1, NHP2P1, Y_RNA, MARCHF5, RNY3P12, MARK2P9.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr13:19,818,121–19,865,048, 4 genes: ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr15:24,954,986–25,000,276, 2 genes (within-gene range 0–2): SNURF, AC124312.1.
- chr15:24,981,994–24,982,068, 1 gene (within-gene range 0–2): SNORD107.
- chr15:50,417,385–50,514,421, 4 genes (within-gene range 0–1): AHCYP7, USP8, RNA5SP395, AC012170.1.
- chr16:58,665,109–58,706,297, 2 genes: SLC38A7, AC012183.1.
- chr17:16,342,534–16,416,689, 5 genes (within-gene range 0–1): CENPV, UBB, AC093484.3, FTLP12, AC093484.2.
- chr18:11,908,712–12,030,877, 5 genes (within-gene range 0–2): AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1.
- chr19:54,906,148–54,916,140, 1 gene: NCR1.
- chr21:10,328,411–13,350,648, 18 genes: AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2.
- chr21:14,075,950–14,076,038, 1 gene (within-gene range 0–1): AP001347.2.
- chr22:24,901,147–24,901,214, 1 gene (within-gene range 0–2): AL049759.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 36 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:135,802,985–135,803,075, 1 gene, copy number 10: MIR5692C1.
- chr7:7,066,964–7,067,045, 1 gene, copy number 11: MIR3683.
- chr7:57,828,331–57,837,046, 2 genes, copy number 13: AC023141.7, AC023141.13.
- chr7:97,963,658–97,967,074, 3 genes, copy number 9: MIR5692A1, MIR5692C2, OR7E38P.
- chr11:3,000,922–3,232,838, 11 genes, copy number 6: CARS1, CARS1-AS1, RNU1-91P, AC108448.3, AC108448.2, OSBPL5, AC108448.1, MRGPRG, MRGPRG-AS1, MRGPRE, AC109309.1.
- chr13:112,313,467–112,321,758, 1 gene, copy number 16: LINC01043.
- chr14:18,614,388–18,637,421, 5 genes, copy number 6: CR383656.6, ARHGAP42P5, LINC02297, CR383656.1, CR383656.12.
- chr16:10,718,633–10,725,296, 8 genes, copy number 7: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr16:29,380,242–29,380,345, 1 gene, copy number 6: AC025279.3.
- chr16:29,475,064–29,505,999, 3 genes, copy number 18: AC133555.2, AC133555.1, NPIPB12.

Autosomal genes at a single copy (total copy number 1): 7,809. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
